CPTAC case C3L-00096 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d52a195d-7d63-4eb6-81c2-3c473ba57979

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1963; Vital status: Dead; Days to death: 71 days; Year of death: 2016; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 52.5 years (19,180 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M1; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 71 days; Progression or recurrence: no; Days to last follow up: 68 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 12.3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 1; Margin status: Involved; Sarcomatoid percent: 30; Sarcomatoid present: Yes.

Follow-up (1 entry)
- Days to follow up: 68 days; Disease response: With Tumor.

Other clinical attributes
- Weight: 93.9 kg; Height: 185 cm; BMI: 27.44.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00096-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 537 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00096-21: Section location: Lower pole; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-00096-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 524 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00096-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
